Surgical pathology report (de-identified scan), TCGA case TCGA-59-2352, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Roswell Park, specimen TCGA-59-2352-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY HISTORY REPORT

DISCLAIMER

THIS IS A HISTORY CASE THAT YOU CANNOT EDIT. TO SEE THE ENTIRE TEXT PLEASE GO TO THE PATIENT HISTORY BY CLICKING THE ELLIPSE (...) NEXT TO THE PATIENT NAME AND CLICKING ON THE HISTORY TAB

DIAGNOSIS:

with pelvic mass & ascites. No chemo/RT

FINAL DIAGNOSIS:

1. OMENTAL biopsy:
- Implants SEROUS CARCINOMA with focal squamous differentiation
2. OVARIES, bilateral, oophorectomy:
- Grade 3 SEROUS CARCINOMA.
- FALLOPIAN TUBES, bilateral, salpingectomy:
- Implants SEROUS CARCINOMA.
- UTERUS, CERVIX, hysterectomy - negative for tumor
- UTERUS, ENDOMETRIUM, hysterectomy:
- METASTATIC SEROUS CARCINOMA.

- UTERUS, MYOMETRIUM, hysterectomy:
- METASTATIC SEROUS CARCINOMA.
- UTERUS, serosa, hysterectomy:
- METASTATIC SEROUS CARCINOMA.
3. PERITONEUM, CUL-DE-SAC, excision:
- Implants SEROUS CARCINOMA.
4. LYMPH NODE, left iliac, excision:
- METASTATIC SEROUS CARCINOMA.
5. LYMPH NODE, right PELVIC, excision:
- METASTATIC SEROUS CARCINOMA.
6. PERITONEUM, SIGMOID COLON, excision:
- Implants SEROUS CARCINOMA.

[page 2 of 4]
[REDACTED]

7. PERITONEUM, COLON NOS, excision:

-Implants SEROUS CARCINOMA.

8. LARGE INTESTINE, TRANSVERSE COLON, excision:

-Implants SEROUS CARCINOMA.

9. SPLEEN, splenectomy:

-Surface implants SEROUS CARCINOMA.

PERITONEUM, GASTROCOLIC LIGAMENT, excision:

-Implants SEROUS CARCINOMA.

10. PERITONEUM, GASTROCOLIC LIGAMENT, excision:

-Implants SEROUS CARCINOMA.

11. PERITONEUM, PARACECAL, excision:

-Implants SEROUS CARCINOMA.

12. PERITONEUM, right PARACOLIC, excision:

-Implants SEROUS CARCINOMA.

13. MESENTERY, SMALL INTESTINE, excision:

-Implants SEROUS CARCINOMA.

DIAGNOSIS COMMENT:

While the tumor is probably primary peritoneal, there is sufficient involvement of the ovaries to warrant a diagnosis of an ovarian primary.

FROZEN SECTION DIAGNOSIS:

1. FS#1 OMENTAL MASS

Poorly differentiated carcinoma by [REDACTED]

2. FS#2 UTERUS, TUBES & OVARIES

Poorly differentiated carcinoma, may be primary but cannot exclude metastatic by [REDACTED]

GROSS DESCRIPTION:

1. FS#1 OMENTAL MASS

Received is one ovoid tissue measuring 2.5x1.5x1.5cm. with tan yellow granular cut surface. Touch prep is done. Frozen sections are made. Representative sections are submitted as follows:

T1, T2

2. FS#2 UTERUS, TUBES & OVARIES

Received is a specimen of uterus, tubes and ovaries weighing 132gm. The cervix and endometrium are unremarkable. The uterus measures overall 9x4x3cm. The endocervical canal measures 4x0.7x0.5cm. The endometrium and the myometrium are unremarkable. The left fallopian tube measures 5cm. and has an external diameter of 0.5cm. and the right fallopian tube measures 1.5cm. and has an external diameter of 0.5cm. Endocervix is [REDACTED]

[page 3 of 4]
located white irregular shaped mucoid cyst measuring 3x2cm. Multiple friable nodules are present on the surface of bilateral ovaries, tubes and the serosal side of the uterus. Ovarian parenchyma is replaced by the tumor. The right ovary measures 3.5x2.5x2.5 cm. The left ovary measures 3x2.8x2.8 cm. One section from the right ovary is frozen. Representative sections are submitted as follows:

FS2,PM1,PM2: parametrium

RFT: right fallopian tube

RO1,2: right ovary

LO1,2: left ovary

LFT: left fallopian tube

PCX: posterior cervix

ACX: anterior cervix

AE1,AE2: anterior endometrium

PE1,PE2: posterior endometrium

3. CUL DE SAC TUMOR

Received in formalin is tan yellow fragment of tissue which has a granular surface and measures in overall dimension 4x4x1cm. Representative sections are submitted in cassettes labelled T1 and T2.

4. LEFT ILIAC LN

Received fresh are two lymph nodes measuring 1x0.7x0.2cm. and the other measuring 1.5x1x0.4cm. Specimen submitted in cassettes labelled LN1 and LN2.

5. RIGHT PELVIC LN

Received is a lymph node measuring 2.3x1x0.5cm. It is submitted in cassette LN1. A smaller lymph node measuring 0.2x0.2cm. is identified which is submitted in the same cassette.

6. TUMOR OVER SIGMOID COLON

Received in formalin is tan yellow granulated mass measuring in overall dimension 3x3x1cm. Representative sections are submitted in cassettes labelled T1 and T2.

7. TUMOR OVER COLON

Received fresh is a tumor which is tan yellow in color and has a granular surface and measures 3.5x2.5x0.8cm. It is submitted in cassette labelled T1.

8. FS#8 TRANSVERSE COLON

Received is transverse colon and omentum and colon with appendix with attached nodular surrounding fat measuring in overall dimension 33x10x3cm. The colon itself measures 33x3x2cm. The mucosa is smooth. No tumor is seen grossly. Cut section shows the omental fat shows a tan yellow tumor that encircles the colonic mucosa. Representative sections are submitted as T1 to

[page 4 of 4]
[REDACTED]

T4.

9. SPLEEN WITH GASTRIC COLIC LIGAMENT TUMOR

Received is a spleen weighing 226gm. measuring in overall dimension 10x5.2x2cm. Cut section shows purplish red parenchyma. No tumor is seen. Attached to the hilum is an indurated mass measuring 8x7x.5x2cm. Representative sections are submitted as follows:

GC1,GC2: gastrocolic ligament

OM: omentum

SP1,SP2: representative sections of spleen

10. GASTRIC COLIC LIGAMENT TUMOR

Received is a tumor which is tan yellow in color with granular surface measuring 7.5x2.5x1cm. Representative section is submitted as T1.

11. TUMOR FROM PARA CECAL AREA

Received fresh is a tumor with is tan yellow in color and granulated measuring 1x1x0.2cm. Representative section is submitted as T1.

12. RT PARA COLIC TUMOR

Received is yellow tan tumor with a granulated surface measuring in overall dimension 4x3.5x0.5cm. Representative section is submitted as T1.

13. SMALL BOWEL MESENTERIC TUMOR

Received is a yellow tan tumor with granular surface measuring 5x3x1cm. Representative section is submitted as T1.

[REDACTED]

Source: NCI Genomic Data Commons file 34fc537e-5304-4738-be1a-346c98e38578 (TCGA-59-2352.15F65643-B84C-4239-BC14-0DDACDFE0425.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).